CCDI case PBBPMG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/9df01ab6-533b-44c9-bc1e-aacd9fdf72f8

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Sarcoma, NOS: ICD-O-3 morphology code: 8800/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 0.8 years (298 days).

Biospecimens (3 samples)
- Sample 0DGSR4: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DGSR7: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DGSRB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
